Somatic mutation profile of tumor specimen TCGA-G3-A3CH-01A (aliquot TCGA-G3-A3CH-01A-11D-A22F-10) from TCGA case TCGA-G3-A3CH, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 53.3 years (19,473 days).
Specimen TCGA-G3-A3CH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6c49eae3-c5c7-4095-9333-47d7171df93d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G3-A3CH-11A (Solid Tissue Normal), aliquot TCGA-G3-A3CH-11A-11D-A22F-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/78bf3bbd-bc30-4bcd-9718-6fce54fe7d06

The open-access MAF lists 45 somatic variants for this specimen: 35 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 9, Nonsense Mutation 2, Intron 1, Splice Region 1, Frame Shift Del 1, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RB1 | c.1498+1del p.X500_splice | Splice Site (DEL) | VAF 48/112 reads (43%) | hotspot (GDC flag); catalogued as CS058010, CS143244, COSV57297471, COSV57311354, COSV57331286, COSV57332387; called by mutect2, pindel, varscan2
- AKR1C2 | c.220G>A p.V74M | Missense Mutation (SNP) | VAF 15/229 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV66332749; called by muse, mutect2
- ANO4 | c.161T>A p.M54K (on ENST00000392977 / NM_001286615.2; = p.V19E on NM_178826.4) | Missense Mutation (SNP) | VAF 35/163 reads (21%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.012); catalogued as COSV54588757; called by muse, mutect2, varscan2
- BCL2 | c.641G>A p.W214* | Nonsense Mutation (SNP) | VAF 35/94 reads (37%) | catalogued as COSV61375339; called by muse, mutect2, varscan2
- BRD7 | c.1388T>A p.L463* | Nonsense Mutation (SNP) | VAF 52/99 reads (53%) | catalogued as COSV67158424; called by muse, mutect2, varscan2
- C16orf90 | c.431C>T p.S144F (on ENST00000399645 / NM_001353385.2; = p.S135F on NM_001080524.2) | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as rs866347257, COSV68714393; called by muse, mutect2, varscan2
- COL6A6 | c.5068C>A p.L1690M | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as COSV62019984; called by muse, mutect2, varscan2
- CRIM1 | c.1688G>A p.R563H | Missense Mutation (SNP) | VAF 7/145 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs965547947, COSV54860775; called by muse, mutect2
- DST | c.8823C>G p.D2941E | Missense Mutation (SNP) | VAF 12/163 reads (7%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.073); catalogued as COSV55002700; called by muse, mutect2
- EXOC3 | c.1634A>G p.E545G | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59266004; called by muse, mutect2
- FBXL6 | c.1039C>G p.R347G | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.533); catalogued as rs782195022, COSV57351114, COSV57352315; called by muse, mutect2, varscan2
- GRIN1 | c.1924A>G p.I642V | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV59293496; called by muse, mutect2, varscan2
- HEATR5B | c.270G>T p.Q90H | Missense Mutation (SNP) | VAF 49/151 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as COSV51850235; called by muse, mutect2, varscan2
- KY | c.198C>T p.H66= | Splice Region (SNP) | VAF 17/60 reads (28%) | catalogued as rs747530241, COSV71016755; called by muse, mutect2, varscan2
- LCK | c.650G>A p.C217Y | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100288281; called by muse, mutect2
- LYST | c.5661A>T p.E1887D | Missense Mutation (SNP) | VAF 83/270 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.009); catalogued as COSV67704408; called by muse, mutect2, varscan2
- LYVE1 | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 99/330 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as rs1003761554, COSV56282355; called by muse, mutect2, varscan2
- MEX3B | c.446G>A p.G149D | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100314273; called by muse, mutect2, varscan2
- MOSPD3 | c.416C>T p.A139V | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.017); catalogued as rs761404739, COSV56157890; called by muse, mutect2, varscan2
- OR1I1 | c.490G>A p.A164T | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.097); catalogued as COSV52917518; called by muse, mutect2
- OR51I1 | c.425G>A p.R142H | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.768); catalogued as rs138548705, COSV66507243; called by muse, mutect2
- PSMD2 | c.749G>A p.R250H | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.143); catalogued as rs11545182, COSV59529155; called by muse, mutect2, varscan2
- SHQ1 | c.457T>A p.L153I | Missense Mutation (SNP) | VAF 56/144 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.904); catalogued as COSV57764436; called by muse, mutect2, varscan2
- SLC9A2 | c.1733C>T p.T578I | Missense Mutation (SNP) | VAF 22/175 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.04); catalogued as COSV52129678; called by muse, mutect2, varscan2
- SNTG2 | c.782C>G p.T261R | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); catalogued as rs530642242, COSV57972278; called by muse, mutect2, varscan2
- SPAG8 | c.1207G>C p.D403H | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52413537, COSV52415254; called by muse, mutect2, varscan2
- SPHKAP | c.743A>T p.Q248L | Missense Mutation (SNP) | VAF 49/174 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as COSV60871686; called by muse, mutect2, varscan2
- TMEM51 | c.245G>A p.C82Y | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as COSV65690447; called by muse, mutect2, varscan2
- TUFT1 | c.618G>C p.R206S | Missense Mutation (SNP) | VAF 9/141 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.272); catalogued as COSV61948093; called by muse, mutect2
- UMODL1 | c.1573T>A p.C525S | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100210861, COSV61159540; called by muse, mutect2, varscan2
- USP38 | c.2759G>T p.R920I | Missense Mutation (SNP) | VAF 72/208 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61025106; called by muse, mutect2, varscan2
- ZNF234 | c.451G>T p.D151Y | Missense Mutation (SNP) | VAF 12/213 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.176); catalogued as COSV70602961; called by muse, mutect2
- PHYHIPL | c.934_955del p.T312Cfs*12 | Frame Shift Del (DEL) | VAF 18/102 reads (18%) | called by mutect2, pindel, varscan2
- TEDC1 | c.965T>C p.F322S (on ENST00000392523 / NM_001367178.1; = p.F253S on NM_001134875.1) | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- TIAL1 | c.189_191del p.A64del | In Frame Del (DEL) | VAF 46/147 reads (31%) | called by pindel, varscan2*
- CEP290 | c.4593T>G p.S1531= | Silent (SNP) | VAF 61/175 reads (35%) | catalogued as COSV58349771; called by muse, mutect2, varscan2
- HIVEP1 | c.1638G>A p.L546= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as rs907790729, COSV65099547; called by muse, mutect2, varscan2
- MDC1 | c.3546C>T p.P1182= | Silent (SNP) | VAF 80/255 reads (31%) | catalogued as rs1275283592, COSV64523725; called by muse, varscan2
- MEX3B | c.447C>A p.G149= | Silent (SNP) | VAF 14/26 reads (54%) | catalogued as COSV100314271, COSV61663697; called by muse, mutect2, varscan2
- OR6F1 | c.873G>A p.T291= | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as rs912568055, COSV57466892; called by muse, mutect2, varscan2
- PAPPA2 | c.1986C>T p.P662= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as COSV100866708, COSV100867070, COSV62774779; called by muse, mutect2, varscan2
- PPT2 | c.789G>A p.G263= | Silent (SNP) | VAF 35/136 reads (26%) | catalogued as COSV61353965; called by muse, mutect2, varscan2
- SPATA31D1 | c.1536C>T p.S512= | Silent (SNP) | VAF 39/196 reads (20%) | catalogued as rs779704681, COSV61193764; called by muse, mutect2, varscan2
- ZNF638 | c.1329G>A p.Q443= | Silent (SNP) | VAF 9/295 reads (3%) | catalogued as COSV100040377; called by muse, mutect2
- NDUFA10 | c.999+6381G>A | Intron (SNP) | VAF 12/118 reads (10%) | catalogued as COSV99401832; called by muse, mutect2
